Surgical pathology report (de-identified scan), TCGA case TCGA-IN-A6RP, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-A6RP-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: SOFT TISSUE, LEFT GASTRIC ARTERY, EXCISION -

- A. MATURE ADIPOSE TISSUE.
- B. THERE IS NO EVIDENCE OF MALIGNANCY.

PART 2: LYMPH NODE, BASE OF LEFT GASTRIC ARTERY, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 3: LYMPH NODE, BASE OF LEFT GASTRIC ARTERY, EXCISION -

- A. MATURE ADIPOSE TISSUE.
- B. THERE IS NO EVIDENCE OF MALIGNANCY.

PART 4: SOFT TISSUE, LEFT GASTRIC ARTERY, EXCISION -
POSITIVE FOR ADENOCARCINOMA.

PART 5: SOFT TISSUE, LEFT GASTRIC ARTERY, EXCISION -

- A. METASTATIC ADENOCARCINOMA TO ONE LYMPH NODE (1/1).
- B. EXTRANODAL LYMPHOVASCULAR INVASION PRESENT.

PART 6: SOFT TISSUE, BASE OF LEFT GASTRIC ARTERY AND VEIN, EXCISION -
METASTATIC ADENOCARCINOMA TO THREE OF FIVE LYMPH NODES (3/5).

PART 7: LYMPH NODE, LEVEL-7, NEAR BRONCHUS INTERMEDIUS, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 8: LYMPH NODE, LEVEL-7, NEAR TAKEOFF RIGHT LOWER LOBE, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 9: LYMPH NODE, LEVEL-7, NEAR CARINA, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES (0/2).

PART 10: LYMPH NODE, PARAESOPHAGEAL, NEAR DIAPHRAGM, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE REACTIVE LYMPH NODE (0/1).

PART 11: LYMPH NODE, PARAESOPHAGEAL, NEAR PERICARDIUM, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 12: LYMPH NODE, PARAESOPHAGEAL, NEAR THORACIC DUCT, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE REACTIVE LYMPH NODE (0/1).

PART 13: ESOPHAGUS AND STOMACH, ESOPHAGOGASTRECTOMY -

- A. ADENOCARCINOMA, MODERATELY TO POORLY DIFFERENTIATED (5.5CM) CENTERED IN DISTAL ESOPHAGUS, INVOLVING THE SUBMUCOSA OF THE GASTROESOPHAGEAL JUNCTION AND STOMACH.
- B. NO MUSCULARIS PROPRIA INVOLVEMENT.
- C. STOMACH WITH FOCAL INTRAEPITHELIAL HIGH GRADE DYSPLASIA.
- D. UNREMARKABLE ESOPHAGEAL SQUAMOUS MUCOSA.
- E. LYMPHOVASCULAR AND PERINEURAL INVASION IDENTIFIED.
- F. PROXIMAL ESOPHAGEAL AND DISTAL GASTRIC AND ADVENTITIAL SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
- G. METASTATIC ADENOCARCINOMA TO SEVEN OF TWENTY-EIGHT LYMPH NODES (7/28).
- H. PATHOLOGIC STAGE: pT1b N3 (SEE SYNOPTIC NOTE).
- I. IMMUNOHISTOCHEMICAL STAIN TO HER2 IS PENDING (SLIDE 13E).

PART 14: STOMACH, GASTRIC RINGS, EXCISION -

- A. UNREMARKABLE SEGMENT OF ESOPHAGUS AND STOMACH.
- B. THERE IS NO EVIDENCE OF MALIGNANCY.

PART 15: STOMACH, FINAL GASTRIC MARGIN, EXCISION -

- A. UNREMARKABLE SEGMENT OF STOMACH.
- B. THERE IS NO EVIDENCE OF MALIGNANCY.

PART 16: SOFT TISSUE, GASTROESOPHAGEAL FAT, EXCISION -

- A. MATURE ADIPOSE TISSUE.
- B. THERE IS NO EVIDENCE OF MALIGNANCY.

PART 17: LYMPH NODE, NEAR GE-JUNCTION, EXCISION -
METASTATIC ADENOCARCINOMA TO ONE LYMPH NODE (1/1).

PART 18: LYMPH NODE, MID PARAESOPHAGEAL, EXCISION -
METASTATIC ADENOCARCINOMA TO ONE LYMPH NODE (1/1).

PART 19: LYMPH NODE, PROXIMAL PARAESOPHAGEAL, EXCISION -

- A. BENIGN FIBROADIPOSE TISSUE.
- B. THERE IS NO EVIDENCE OF MALIGNANCY.

Collection Date:

ICD-O-3

Adenocarcinoma NOS
8140/3

Site Gastroesophageal
junction C16.0

Op 7/23/13

[page 2 of 2]
PART 20: LYMPH NODE, SUBCARINAL, NEAR TRACHEA, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN FIVE LYMPH NODES (0/5).
PART 21: LYMPH NODE, SUBCARINAL, ESOPHAGUS, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODE (0/2).

PART 22: LYMPH NODE, SUBCARINAL, NEAR AZYGOS, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1).

PART 23: LYMPH NODE SUBCARINAL LYMPH NODE, EXCISION -
THERE IS NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES (0/2).

Addendum

Immunohistochemical stain to HER2 shows equivocal (2+), weak to moderate membranous staining in 10% of tumor cells.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS

----- MACROSCOPIC -----

SPECIMEN TYPE: Esophagogastrectomy
TUMOR SITE: Tumor midpoint in distal esophagus AND tumor involves esophagogastric junction
TUMOR SIZE: Greatest dimension: 5.5 cm
Additional dimensions: 3 X 1.3 cm

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: G3

PATHOLOGIC STAGING (pTNM)

pT1b
pN3
Number of lymph nodes examined: 28
Number of lymph nodes involved: 7
pM Not applicable
No prior treatment

PRIOR TREATMENT: MARGINS

Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Circumferential (adventitial) margin uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 0.7 mm
Specify margin: Adventitial margin

ANGIOLYMPHATIC INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS: Other: Intraepithelial high grade dysplasia and intestinal metaplasia of gastric mucosa

SPECIAL PROCEDURES:

In Situ Procedure

Interpretation

HER2 FISH STUDIES PERFORMED ON THE ADENOCARCINOMA ARE POSITIVE.

Cells Analyzed: 100

Ratio HER2/CEP17: 2.38

SNR: 4.0

CNR: 1.7

% Hyperdiploid: 13(13.0%)

Results

Probe: HER2 DNA Probe

Probe Description: The HER2 DNA probe is a 190 Kb directly labeled fluorescent DNA probe specific for the HER2 gene locus (17q11.2-q12). The CEP 17 DNA probe is a 5.4 Kb directly labeled fluorescent DNA probe specific for the alpha satellite DNA sequence at the centromeric region of chromosome 17 (17p11.1-q11.1). The probes are pre-mixed and pre-denatured in hybridization buffer.

Interpretation:

HER2 negative: HER2 gene/chromosome 17 ratio less than 2.0

HER2 positive: HER2 gene/chromosome 17 ratio greater than 2.0

Results should be considered along with other clinical information.

has modified the suggested manufacturer protocol for HER2 FISH testing.

The modifications have been tested and validated. The modifications are as follows: Slides are deparaffinized Tissue is digested in protease 31 minutes; Tissue and probe are co-denatured at 90 C for 12 minutes; Paraffin pretreatment reagents and control slides are prepared in house. Amplified, non-amplified, and internal (centromere 17) controls were used in the testing. The laboratory takes responsibility for the test performance.

FISH analysis was manually performed and quantitatively assessed by analysis of a minimum of 60 cells using the HER2 and the CEP17 probes.

Source: NCI Genomic Data Commons file 75607993-2b90-46d7-b7ce-13c715d876a5 (TCGA-IN-A6RP.966DE898-685F-4297-8459-8CFC8D170A8F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).